Surgical pathology report (de-identified scan), TCGA case TCGA-D6-A74Q, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-A74Q-01A (Primary Tumor).

Patient: XXX

Age

Gender: M

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) **Cancer of the larynx -**

Date of admission

*ICD O-3
Carcinoma, squamous cell
keratinizing NOS 8071/3
Site Larynx NOS C32.9
9/26/13*

Material:

1) Material: larynx, Method of collection: Collection of specimens for laboratory examination

Histopathological diagnosis:

Examination performed on

Invasive keratinizing squamous cell carcinoma (G3) of the larynx.

Excision lines at the side of the root of the tongue and trachea are free of cancerous lesions.

Margin of the excision at the front right side is below 0.1 cm.

pT4a. (8071/3 T-24100)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Surgical specimen sized: 9 x 5 x 4 cm, including the larynx with the hyoid bone and part of the trachea 2.5 cm in length.

In the region of glottis, at the right and left side there is a tumour sized: 2.5 x 2.5 x 1.5 cm invading the subglottal region, supraglottal region, thyroid cartilage and pre-epiglottic space.

Assistant:

Pathologist:

Edited by

Results of intraoperative examination:

Examination performed on.

Margins at the side of the root of the tongue (1 wire) and trachea (2 wires) are free of cancerous lesions.

Assistant:

Pathologist:

Edited by

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 1caff27a-b27d-4975-97cc-4db2a636bade (TCGA-D6-A74Q.11F45993-E238-4B93-9ACF-9B35F2A3FF1E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).